Somatic mutation profile of tumor specimen TCGA-04-1542-01A (aliquot TCGA-04-1542-01A-01W-0553-09) from TCGA case TCGA-04-1542, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 52.7 years (19,263 days).
Specimen TCGA-04-1542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce4680d7-580d-4472-91fc-a05848888a5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1542-10A (Blood Derived Normal), aliquot TCGA-04-1542-10A-01W-0553-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c4a467c-49ae-4974-9977-f8ab908bbe91

The open-access MAF lists 71 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 12, Nonsense Mutation 4, Intron 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 66/72 reads (92%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL9L | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1315049646, COSV52688019; called by muse, mutect2, varscan2
- BICC1 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV54065789; called by muse, mutect2, varscan2
- BNC1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61757496; called by muse, mutect2, varscan2
- CHAMP1 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV63522945; called by muse, mutect2, varscan2
- CNTNAP2 | c.2641C>A p.Q881K | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV62236484; called by muse, mutect2, varscan2
- COL3A1 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58594437; called by muse, mutect2, varscan2
- DAGLA | c.2150A>C p.D717A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57198799; called by muse, mutect2, varscan2
- DRD1 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67105081; called by muse, mutect2, varscan2
- DTX2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV56861092, COSV56864136; called by muse, mutect2, varscan2
- ENTPD1 | c.1326+2T>C p.X442_splice | Splice Site (SNP) | VAF 90/203 reads (44%) | catalogued as COSV64603746; called by muse, mutect2, varscan2
- ESRRG | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs761583933, COSV63158526, COSV63174861; called by muse, mutect2, varscan2
- FEZ2 | c.705C>A p.Y235* | Nonsense Mutation (SNP) | VAF 33/134 reads (25%) | catalogued as COSV59907054; called by muse, mutect2, varscan2
- GET3 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1398649782, COSV62001918; called by muse, mutect2
- IL12RB2 | c.296T>G p.F99C | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52026116; called by muse, mutect2, varscan2
- IRS1 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV100524403; called by muse, mutect2
- JMJD6 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1366225731; called by muse, mutect2
- KCNA4 | c.1409C>A p.T470N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60254974; called by muse, mutect2, varscan2
- KIAA1217 | c.4733del p.P1578Lfs*26 | Frame Shift Del (DEL) | VAF 228/1085 reads (21%) | catalogued as COSV56815903; called by mutect2, pindel, varscan2
- LDLRAD4 | c.43T>A p.C15S | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63341519; called by muse, mutect2, varscan2
- LHX9 | c.118A>G p.R40G | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61330672; called by muse, mutect2, varscan2
- LRFN5 | c.2083G>C p.A695P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53269991; called by muse, mutect2, varscan2
- MACC1 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV60545387; called by muse, mutect2, varscan2
- MBD1 | c.1211G>A p.R404H (on ENST00000269468 / NM_001323950.1; = p.R348H on NM_002384.2) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs769115388, COSV54005532; called by muse, mutect2, varscan2
- MLIP | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV51434811; called by muse, mutect2, varscan2
- MOV10 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV53518912; called by muse, varscan2
- MYBL1 | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV72919148; called by muse, mutect2, varscan2
- MYO3A | c.4198C>T p.H1400Y | Missense Mutation (SNP) | VAF 115/537 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV56343432; called by muse, mutect2, varscan2
- NALCN | c.300T>G p.S100R | Missense Mutation (SNP) | VAF 106/353 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV51956029; called by muse, mutect2, varscan2
- NLRP3 | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 137/379 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as rs180177500, COSV60219174, COSV60229456, COSV60229489; called by muse, mutect2, varscan2
- NOD2 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56053835; called by muse, mutect2, varscan2
- NYAP2 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV56013544; called by muse, mutect2, varscan2
- ODF4 | c.526T>A p.S176T | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60272668; called by muse, mutect2, varscan2
- OR8H3 | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100538913; called by muse, mutect2
- OSBPL1A | c.1652G>C p.S551T (on ENST00000319481 / NM_080597.4; = p.S38T on NM_018030.4) | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV60202013; called by muse, mutect2, varscan2
- PACS1 | c.2125C>G p.R709G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749297584; called by muse, mutect2, varscan2
- PCDHA9 | c.425T>A p.I142N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1554142573, COSV100969411; called by muse, mutect2, varscan2
- PDE11A | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as COSV53704601, COSV99613176; called by muse, mutect2, varscan2
- PDIA4 | c.1726C>G p.Q576E (on ENST00000286091 / NM_001371244.1; = p.Q575E on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53726132; called by muse, mutect2, varscan2
- PGLYRP2 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52996718; called by muse, mutect2, varscan2
- PLOD1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs372534520, COSV99537970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF4B | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 102/409 reads (25%) | catalogued as COSV61784569; called by muse, mutect2, varscan2
- QPRT | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs919913651, COSV54879033; called by muse, mutect2, varscan2
- RASSF2 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV65082884, COSV65083210; called by muse, mutect2, varscan2
- SASS6 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.39); catalogued as COSV54929573; called by muse, mutect2, varscan2
- SCN8A | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 165/367 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); catalogued as rs1229931495, COSV61977665; called by muse, mutect2, varscan2
- SHOX2 | c.380C>T p.A127V (on ENST00000441443 / NM_006884.3; = p.A151V on NM_003030.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs747319392, COSV67463867; called by muse, mutect2, varscan2
- SLCO1C1 | c.1439G>A p.C480Y | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56877627; called by muse, mutect2, varscan2
- SLITRK3 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1490316717, COSV53852040; called by muse, mutect2, varscan2
- SVEP1 | c.567A>T p.K189N | Missense Mutation (SNP) | VAF 138/256 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57044378; called by muse, mutect2, varscan2
- TBC1D1 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | catalogued as rs759798838, COSV54724891; called by muse, mutect2, varscan2
- TCERG1L | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV64054868; called by muse, mutect2
- TOP3A | c.2247C>A p.D749E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV100329031; called by muse, mutect2
- TTN | c.100769C>T p.P33590L (on ENST00000591111; = p.P26166L on NM_003319.4) | Missense Mutation (SNP) | VAF 113/431 reads (26%) | PolyPhen possibly damaging (0.898); catalogued as COSV60256672; called by muse, mutect2, varscan2
- VPS13B | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1157527106, COSV62023956; called by muse, mutect2, varscan2
- ZC3HAV1 | c.489C>A p.N163K | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV54299661; called by muse, mutect2, varscan2
- RARB | c.739_742dup p.G248Afs*26 (on ENST00000383772 / NM_001290216.2; = p.G241Afs*26 on NM_000965.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 41/86 reads (48%) | called by mutect2, varscan2
- BARHL2 | c.921G>A p.L307= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100966047; called by muse, mutect2, varscan2
- CCDC144A | c.720C>T p.C240= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as rs772414094, COSV60700708; called by muse, mutect2, varscan2
- CCRL2 | c.756G>A p.A252= | Silent (SNP) | VAF 244/536 reads (46%) | catalogued as rs557325885, COSV100645011; called by muse, mutect2, varscan2
- DMD | c.1911C>A p.T637= | Silent (SNP) | VAF 49/61 reads (80%) | catalogued as rs928561454, COSV55892891; ClinVar: likely benign; called by muse, mutect2, varscan2
- IHO1 | c.1737T>C p.N579= | Silent (SNP) | VAF 107/228 reads (47%) | catalogued as COSV56509431; called by muse, mutect2, varscan2
- ITGBL1 | c.342G>A p.K114= | Silent (SNP) | VAF 139/389 reads (36%) | catalogued as rs369818869; called by muse, mutect2, varscan2
- KIF13A | c.1212A>G p.K404= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV52461728, COSV52468182; called by muse, mutect2
- NOTCH4 | c.1032G>C p.V344= | Silent (SNP) | VAF 71/386 reads (18%) | catalogued as COSV66682963; called by muse, mutect2, varscan2
- OR8B8 | c.450G>T p.G150= | Silent (SNP) | VAF 11/279 reads (4%) | called by muse, mutect2
- SLC30A9 | c.288C>T p.G96= | Silent (SNP) | VAF 61/202 reads (30%) | catalogued as rs762600163, COSV52558348; called by muse, mutect2, varscan2
- SLC5A7 | c.891A>C p.S297= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV50898274; called by muse, mutect2, varscan2
- TEFM | c.513A>C p.I171= | Silent (SNP) | VAF 28/178 reads (16%) | catalogued as COSV58977549; called by muse, mutect2, varscan2
- H2BP2 | n.1061+588T>A | Intron (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- MFSD4B | c.*723C>A | 3'UTR (SNP) | VAF 68/207 reads (33%) | catalogued as COSV64349342; called by muse, mutect2, varscan2
